Somatic mutation profile of tumor specimen TCGA-KK-A6E8-01A (aliquot TCGA-KK-A6E8-01A-11D-A31L-08) from TCGA case TCGA-KK-A6E8, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.5 years (25,026 days).
Specimen TCGA-KK-A6E8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d624e8f4-a491-4739-916c-174a7dedd1de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E8-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E8-11A-11D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4147c29b-0fad-4997-8fce-2f17f8432390

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 26, Silent 10, In Frame Del 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALKBH2 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs140769082; called by muse, mutect2, varscan2
- ARFGAP3 | c.1321T>C p.Y441H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV54312404; called by muse, mutect2, varscan2
- ASNSD1 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV53623954; called by muse, mutect2, varscan2
- COL4A5 | c.4949C>G p.A1650G | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV60363852, COSV60372838; called by muse, mutect2, varscan2
- EFCAB7 | c.726A>T p.K242N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV64314757; called by muse, mutect2, varscan2
- FBLN1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53049030, COSV99410759; called by muse, mutect2, varscan2
- GLRA1 | c.994G>C p.V332L | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV51015581, COSV99199739; called by muse, mutect2, varscan2
- HMOX2 | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as rs1166901516, COSV54860597, COSV54862087; called by muse, mutect2
- KDM6A | c.3349A>T p.N1117Y | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV65041718; called by muse, mutect2, varscan2
- L34079.1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1392318784, COSV60670890; called by muse, mutect2
- LAMA2 | c.3893A>G p.Q1298R | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV70350207; called by muse, mutect2, varscan2
- LAMA3 | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs369896333; called by muse, mutect2, varscan2
- LRRC4C | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53428576; called by muse, varscan2
- MAMSTR | c.857C>T p.S286L (on ENST00000318083 / NM_001130915.2; = p.S183L on NM_182574.2) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58881894; called by muse, mutect2, varscan2
- MUC16 | c.28675A>G p.M9559V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV67473323; called by muse, mutect2, varscan2
- OR5B3 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV58677741; called by muse, mutect2, varscan2
- PCDHB6 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs781793464, COSV50701880, COSV50734398; called by muse, mutect2
- PTCHD4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV59787657; called by muse, mutect2, varscan2
- RELL1 | c.397G>T p.V133F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV58452322; called by muse, mutect2, varscan2
- RHOB | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55356584; called by muse, mutect2
- SGTA | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV55594287; called by muse, mutect2, varscan2
- SNRPD2 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV50004045; called by muse, mutect2, varscan2
- SRFBP1 | c.789T>A p.D263E | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59583250; called by muse, mutect2
- SYCP2 | c.2293C>T p.Q765* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV62769179; called by muse, mutect2, varscan2
- TMCO4 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 264/634 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs146596460; called by muse, mutect2, varscan2
- UNC13C | c.5962T>C p.Y1988H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52885086; called by muse, mutect2, varscan2
- ZNF326 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV61035559, COSV61036143; called by muse, mutect2, varscan2
- ARHGDIA | c.463_465del p.E155del | In Frame Del (DEL) | VAF 8/54 reads (15%) | called by pindel, varscan2
- FOXA1 | c.754_780del p.N252_L260del | In Frame Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel
- GBP3 | c.506_507del p.F169Cfs*29 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- AOPEP | c.636T>A p.A212= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV52919204; called by muse, mutect2, varscan2
- CACNB4 | c.1296G>A p.G432= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV52395781; called by muse, mutect2, varscan2
- CD34 | c.744C>T p.A248= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV60413609; called by muse, mutect2, varscan2
- DES | c.894G>T p.S298= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV64660457, COSV64661079; called by muse, mutect2, varscan2
- HMCN1 | c.9348C>T p.H3116= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as rs571746652, COSV54900432; called by muse, mutect2, varscan2
- LRRC4C | c.375C>T p.N125= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV53428588; called by muse, varscan2
- MGAT4C | c.1020C>T p.N340= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100153043, COSV59836037; called by muse, mutect2
- MIA3 | c.3324G>C p.L1108= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV60514121; called by muse, mutect2
- SHANK1 | c.2787G>T p.P929= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV53253292, COSV53260616; called by muse, mutect2, varscan2
- WDR3 | c.408G>T p.V136= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV62523650; called by muse, mutect2, varscan2
